Somatic mutation profile of tumor specimen TCGA-18-3408-01A (aliquot TCGA-18-3408-01A-01D-0983-08) from TCGA case TCGA-18-3408, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.1 years (28,171 days).
Specimen TCGA-18-3408-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f4972ef-3782-4c22-9915-4245df48e38c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3408-11A (Solid Tissue Normal), aliquot TCGA-18-3408-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2330db7c-3956-40a6-a52e-816ccccc4709

The open-access MAF lists 87 somatic variants for this specimen: 67 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 19, Nonsense Mutation 7, Frame Shift Ins 3, In Frame Del 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAAF1 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as rs267607225, CM099268, COSV57577151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 68/95 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC008397.2 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); catalogued as rs553070308, COSV53206804, COSV99441375; called by muse, mutect2, varscan2
- ACTL6A | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV66998932; called by muse, mutect2
- ADAM21 | c.890T>C p.M297T | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs766109818, COSV50792809; called by muse, mutect2, varscan2
- ADCY2 | c.1211A>G p.D404G | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57871199; called by muse, mutect2, varscan2
- AKR1D1 | c.698T>A p.V233D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as COSV54337371; called by muse, mutect2, varscan2
- ANKRD34A | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV60160896; called by muse, mutect2, varscan2
- ARL13A | c.496T>A p.S166T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV65880121; called by muse, mutect2
- ATXN2 | c.3833A>G p.Q1278R (on ENST00000550104; = p.Q1118R on NM_002973.4) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV57983148; called by muse, mutect2
- BBC3 | c.656C>T p.P219L (on ENST00000449228 / NM_001127240.3; = p.H185Y on NM_014417.5) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); catalogued as COSV56262671; called by muse, mutect2, varscan2
- BSN | c.4587G>T p.M1529I | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV56517466; called by muse, mutect2, varscan2
- CCDC38 | c.594G>C p.M198I | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV60183046; called by muse, mutect2, varscan2
- CDH23 | c.3716G>A p.G1239E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56462330; called by muse, mutect2, varscan2
- CHD2 | c.3582A>T p.E1194D | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV67708921; called by muse, mutect2, varscan2
- CREBBP | c.3419G>A p.R1140Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52119302; called by muse, mutect2, varscan2
- DLGAP2 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV70097717; called by muse, mutect2, varscan2
- FAM120C | c.3065T>A p.L1022Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.358); catalogued as COSV60259221; called by muse, mutect2, varscan2
- FAM171A1 | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757886041, COSV65315862; called by muse, mutect2, varscan2
- FAM221B | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV65074319; called by muse, mutect2, varscan2
- FAT4 | c.10924G>A p.D3642N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58683502; called by muse, mutect2, varscan2
- FOLR3 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV61530146; called by muse, mutect2, varscan2
- GALNT8 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.438); catalogued as rs375631897; called by muse, mutect2
- GJC1 | c.1076A>G p.Q359R | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV57911199; called by muse, mutect2, varscan2
- HLA-DPA1 | c.115A>T p.T39S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV70088929; called by muse, mutect2, varscan2
- HNF1A | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV57462082; called by muse, mutect2, varscan2
- HYDIN | c.11711T>C p.I3904T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV66636665, COSV66638896; called by muse, mutect2, varscan2
- IMPACT | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV52421924; called by muse, mutect2, varscan2
- INHBA | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54221462; called by muse, mutect2, varscan2
- KIF13B | c.2992C>A p.Q998K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV72954381; called by muse, mutect2, varscan2
- KIF3A | c.1355A>G p.E452G | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV66414424; called by muse, mutect2, varscan2
- KLC2 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs1294097402, COSV57582518; called by muse, mutect2, varscan2
- METTL6 | c.354T>A p.Y118* | Nonsense Mutation (SNP) | VAF 31/50 reads (62%) | catalogued as COSV67542086; called by muse, mutect2, varscan2
- MIER3 | c.1129C>G p.R377G (on ENST00000381199 / NM_001297599.2; = p.R376G on NM_152622.4) | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV67082794; called by muse, mutect2, varscan2
- MYH8 | c.2557G>A p.A853T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1319449107, COSV67964615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1D | c.2614G>T p.V872L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV59012530; called by mutect2, varscan2
- NEK8 | c.561G>A p.W187* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV52044850; called by muse, mutect2, varscan2
- NEXMIF | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362175878, COSV50030044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4D11 | c.805A>C p.K269Q | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV57585536; called by muse, mutect2, varscan2
- PCLO | c.13385A>G p.K4462R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV61633762; called by muse, mutect2, varscan2
- PLD4 | c.667C>G p.R223G | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV66915132; called by muse, mutect2, varscan2
- PREX1 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV64251476; called by muse, mutect2, varscan2
- PRIMPOL | c.236T>G p.L79R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59248772; called by muse, mutect2, varscan2
- PTPN13 | c.1010C>G p.P337R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV57407080; called by muse, mutect2, varscan2
- ROBO2 | c.2897C>T p.T966M | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as rs767565581, COSV59910187; called by mutect2, varscan2
- SERPINI1 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55509990; called by muse, mutect2, varscan2
- SLC9A3 | c.1530C>A p.F510L | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53800998; called by muse, mutect2, varscan2
- STK32C | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53840552; called by muse, mutect2, varscan2
- TDRD5 | c.20T>C p.I7T | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs764470335, COSV54242387; called by muse, mutect2, varscan2
- TLR7 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV66124247; called by mutect2, varscan2
- TLR8 | c.989G>T p.G330V (on ENST00000218032 / NM_138636.5; = p.G348V on NM_016610.4) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54317859; called by muse, mutect2, varscan2
- TRIML1 | c.782G>T p.C261F | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.28); catalogued as COSV60194216; called by muse, mutect2, varscan2
- TUBA3C | c.164A>C p.E55A | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as COSV67139249; called by muse, mutect2
- TUBA3C | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 12/131 reads (9%) | catalogued as COSV67139252; called by muse, mutect2
- UBE2Q2 | c.319T>C p.C107R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51192971; called by muse, mutect2, varscan2
- UGT1A7 | c.794T>A p.V265E | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60838561; called by muse, mutect2, varscan2
- UHRF1 | c.340G>T p.A114S (on ENST00000612630 / NM_001290050.1; = p.A127S on NM_013282.4) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.82); PolyPhen benign (0.028); catalogued as COSV53574504; called by muse, mutect2, varscan2
- VPS52 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291596778, COSV71403394; called by muse, mutect2, varscan2
- ZBTB18 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as COSV62396661, COSV62396900; called by muse, mutect2, varscan2
- ZXDC | c.1778A>G p.Q593R | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV60446946; called by muse, mutect2, varscan2
- FOXP1 | c.1297_1303del p.G433Sfs*39 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- IGKV1-12 | c.16C>G p.P6A | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- IL1RAPL2 | c.402dup p.E135Rfs*3 | Frame Shift Ins (INS) | VAF 90/165 reads (55%) | called by mutect2, pindel, varscan2
- KLK11 | c.826dup p.Q276Pfs*32 (on ENST00000594768 / NM_144947.3; = p.Q244Pfs*32 on NM_006853.3) | Frame Shift Ins (INS) | VAF 56/180 reads (31%) | called by mutect2, pindel, varscan2
- NFE2L2 | c.206_232del p.A69_D77del | In Frame Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel
- SRPK1 | c.1046dup p.G350Wfs*6 | Frame Shift Ins (INS) | VAF 27/97 reads (28%) | called by mutect2, pindel, varscan2
- VN1R5 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AOC2 | c.960A>G p.Q320= | Silent (SNP) | VAF 47/111 reads (42%) | catalogued as rs1273895843, COSV53199077; called by muse, mutect2, varscan2
- BPIFB4 | c.222A>G p.V74= | Silent (SNP) | VAF 64/192 reads (33%) | catalogued as rs746006780, COSV64951150; called by muse, mutect2
- CACNA1I | c.3774C>T p.S1258= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV60807647; called by muse, mutect2, varscan2
- GLB1L2 | c.1842G>A p.E614= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV56996783; called by muse, mutect2, varscan2
- IGLV5-37 | c.84C>A p.S28= | Silent (SNP) | VAF 99/139 reads (71%) | called by muse, mutect2, varscan2
- INTS5 | c.2577G>A p.E859= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV57951436; called by muse, mutect2, varscan2
- KIAA1109 | c.4044T>C p.S1348= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV52671912; called by muse, mutect2, varscan2
- KIR2DL1 | c.933A>G p.T311= | Silent (SNP) | VAF 113/332 reads (34%) | catalogued as COSV99383602; called by muse, mutect2, varscan2
- KRTAP12-2 | c.315C>T p.C105= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs371213509; called by muse, mutect2, varscan2
- NLRP7 | c.2202G>A p.T734= (on ENST00000340844 / NM_206828.3; = p.T706= on NM_139176.3) | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs141917868; called by muse, mutect2, varscan2
- OR4P4 | c.543T>C p.P181= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as COSV58921895; called by muse, mutect2, varscan2
- PBX1 | c.489G>C p.T163= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV61533933, COSV61537251; called by muse, mutect2, varscan2
- PCDHB4 | c.1278G>C p.G426= | Silent (SNP) | VAF 57/99 reads (58%) | catalogued as COSV52022179; called by muse, mutect2, varscan2
- SFN | c.579G>A p.L193= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV59433202; called by muse, mutect2, varscan2
- SLC5A1 | c.1887G>A p.K629= | Silent (SNP) | VAF 75/113 reads (66%) | catalogued as rs1323644344, COSV56685213; called by muse, mutect2, varscan2
- SLFN11 | c.612C>T p.I204= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV57697922, COSV57698585; called by muse, mutect2, varscan2
- STH | c.81C>T p.C27= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as rs763740965, COSV52239658; called by muse, mutect2
- ZC3H3 | c.399T>G p.S133= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV52789633; called by muse, mutect2
- ZNF683 | c.1332C>T p.H444= (on ENST00000403843; = p.H424= on NM_173574.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV62874243; called by muse, varscan2
- MIR890 | n.9C>T | RNA (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
